Somatic mutation profile of tumor specimen TCGA-BR-8285-01A (aliquot TCGA-BR-8285-01A-11D-2340-08) from TCGA case TCGA-BR-8285, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.1 years (20,849 days).
Specimen TCGA-BR-8285-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5131d045-4ec5-4a34-a236-d94220f4d2c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8285-10A (Blood Derived Normal), aliquot TCGA-BR-8285-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a5d15a4-0734-4fbc-886f-274593983451

The open-access MAF lists 105 somatic variants for this specimen: 81 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 23, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM2 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs769082387, COSV55864232; called by muse, mutect2, varscan2
- ADAMTS7 | c.4981C>T p.R1661C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1464738332, COSV101183023; called by muse, mutect2
- AFTPH | c.108A>C p.E36D | Missense Mutation (SNP) | VAF 44/325 reads (14%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.63); catalogued as COSV99480347; called by muse, mutect2, varscan2
- ALOXE3 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV100559629; called by muse, mutect2
- ARFGEF2 | c.5033C>T p.S1678F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs573621508, COSV100904034; called by muse, mutect2, varscan2
- ARHGAP45 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs771684898, COSV100490459; called by muse, mutect2, varscan2
- ASXL3 | c.3163G>A p.A1055T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1165991321, COSV52462427; called by muse, mutect2, varscan2
- BEX4 | c.278A>G p.K93R | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV101015328; called by muse, mutect2, varscan2
- BTN1A1 | c.1287A>C p.E429D | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV55070058; called by muse, mutect2, varscan2
- CASP8 | c.1303C>T p.R435* (on ENST00000432109 / NM_033355.3; = p.R452* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 23/161 reads (14%) | catalogued as rs1368296717, COSV51844657; called by muse, mutect2, varscan2
- CEP170B | c.2516T>G p.V839G (on ENST00000453495; = p.V768G on NM_015005.3) | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs1479621348, COSV101371410; called by muse, mutect2
- CTSG | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV53534971; called by muse, mutect2, varscan2
- DLG2 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV99713025; called by muse, mutect2
- DNAJB9 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 33/349 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV99974403; called by muse, mutect2
- DOCK5 | c.5342C>T p.S1781L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99376208; called by muse, mutect2
- FAM161A | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs780565318, COSV100281145; called by muse, mutect2, varscan2
- FAM174A | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100444297, COSV57062823; called by muse, mutect2, varscan2
- FBXO10 | c.54G>T p.L18F | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV99446300; called by muse, mutect2, varscan2
- FCMR | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100892832; called by muse, mutect2, varscan2
- FNDC11 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.006); catalogued as COSV64442650; called by muse, mutect2, varscan2
- FNDC3A | c.3161A>G p.K1054R (on ENST00000492622 / NM_001079673.2; = p.K998R on NM_014923.5) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV101256633; called by mutect2, varscan2
- FRYL | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs770421552, COSV99976025; called by muse, mutect2, varscan2
- GABRB1 | c.1120A>C p.I374L | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99780416; called by muse, mutect2, varscan2
- GPR26 | c.725A>C p.K242T | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.644); catalogued as COSV99500773; called by muse, mutect2
- HCFC1 | c.3872A>G p.N1291S | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs1557113873, COSV100128509; called by muse, mutect2, varscan2
- HCK | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 47/443 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as rs555782474, COSV99393787; called by muse, mutect2, varscan2
- HMCN1 | c.4519G>A p.G1507R | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV99624944; called by muse, mutect2, varscan2
- HMCN1 | c.16130C>A p.P5377H | Missense Mutation (SNP) | VAF 62/446 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV54945990, COSV99624948; called by muse, mutect2, varscan2
- HOXD10 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99982573; called by muse, mutect2, varscan2
- IGSF10 | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs374899455; called by muse, mutect2, varscan2
- IRX1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV57360538; called by muse, mutect2
- ISLR2 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as COSV62303546; called by muse, mutect2
- JAG2 | c.2515G>A p.G839R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781734780, COSV100077958; called by muse, mutect2, varscan2
- KCNAB2 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.238); catalogued as rs758297152, COSV99378728; called by muse, mutect2, varscan2
- LRP2 | c.9849G>T p.K3283N | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99786795; called by muse, mutect2, varscan2
- LRRTM3 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63663962; called by muse, mutect2, varscan2
- MC4R | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs13447335, CM030235, COSV55352021; called by muse, mutect2
- MGA | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54958518; called by muse, mutect2
- MKLN1 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV100759704; called by muse, mutect2, varscan2
- MYH2 | c.3584C>T p.A1195V | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs373108053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKTR | c.2768G>T p.S923I | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99235279; called by muse, mutect2, varscan2
- NLRP4 | c.2896A>G p.T966A | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV100015720; called by muse, mutect2
- NMS | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1198354512, COSV65259300; called by muse, mutect2
- OR2T12 | c.584A>C p.N195T | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.216); catalogued as COSV100528005, COSV58775968; called by muse, mutect2
- OTOA | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs140152105, COSV99625617; called by muse, mutect2
- PAX2 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770252038, COSV100694992, COSV62290083; called by muse, mutect2, varscan2
- PCDH1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.382); catalogued as rs770603781, COSV99745597; called by muse, mutect2, varscan2
- PCDHGB7 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99532236; called by muse, mutect2, varscan2
- PDP1 | c.362C>G p.A121G | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as COSV99891980; called by muse, mutect2, varscan2
- PIK3CB | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.523); catalogued as rs1217537873, COSV56683158; called by muse, mutect2, varscan2
- PLK1 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99890740; called by muse, mutect2, varscan2
- PPP1R10 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs771196483, COSV100919758; called by muse, varscan2
- PRX | c.4306C>T p.R1436W | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs1332674327, COSV99396402; called by muse, mutect2
- RALB | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55603155, COSV55604583; called by muse, mutect2, varscan2
- RASD2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs368099253; called by muse, mutect2, varscan2
- RELN | c.8212C>T p.R2738W | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs202166176, COSV59035750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REPS2 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771385168, COSV100380870; called by muse, mutect2, varscan2
- RPF1 | c.617-1G>A p.X206_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as rs1288845944, COSV101035382; called by muse, mutect2, varscan2
- SCAMP5 | c.396C>T p.C132= | Splice Region (SNP) | VAF 43/308 reads (14%) | catalogued as rs760675585, COSV100723791; called by muse, mutect2, varscan2
- SCRN1 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99620922; called by muse, mutect2
- SLAMF9 | c.185C>G p.A62G | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100928108; called by muse, mutect2
- SLC1A7 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1373611400, COSV65195930; called by muse, mutect2, varscan2
- SLC6A1 | c.1704A>C p.Q568H | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99822463; called by muse, mutect2, varscan2
- SLIT2 | c.2570G>A p.G857E | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99881480; called by muse, mutect2, varscan2
- SYT7 | c.206A>C p.K69T | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV99801190; called by muse, mutect2
- TAS2R13 | c.884T>G p.V295G | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV101183716; called by muse, mutect2, varscan2
- TBC1D25 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.074); catalogued as rs905111666, COSV100952114; called by muse, mutect2
- TBX18 | c.1074A>T p.E358D | Missense Mutation (SNP) | VAF 56/489 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100858389, COSV100858446; called by muse, mutect2, varscan2
- TCF20 | c.814T>A p.Y272N | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100166326; called by muse, varscan2
- TIE1 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs759402690, COSV100992009; called by muse, mutect2
- TMEM108 | c.13T>G p.L5V | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.92); catalogued as COSV100418428; called by muse, mutect2, varscan2
- TRIO | c.2186A>C p.K729T | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as COSV100709972, COSV60093896; called by muse, mutect2
- XKR9 | c.65T>C p.L22S | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101281832; called by muse, mutect2, varscan2
- ZCCHC2 | c.2594C>T p.T865M | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs762756414, COSV99502172; called by muse, mutect2, varscan2
- ZNF236 | c.3133C>A p.H1045N | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1220099257, COSV99469301; called by muse, mutect2, varscan2
- ZNF257 | c.326A>T p.E109V | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV101448034; called by muse, mutect2
- ZNF568 | c.485T>G p.F162C | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100451187; called by muse, mutect2, varscan2
- IKZF5 | c.787del p.S263Pfs*15 | Frame Shift Del (DEL) | VAF 22/196 reads (11%) | called by mutect2, pindel, varscan2
- IRF2 | c.870del p.T291Pfs*27 | Frame Shift Del (DEL) | VAF 36/237 reads (15%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.1298T>A p.I433N | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TAF15 | c.1740-2A>T p.X580_splice (on ENST00000605844 / NM_139215.3; = p.X577_splice on NM_003487.4) | Splice Site (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2
- ABCD1 | c.1252C>A p.R418= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as CD961756, CM940031, COSV99497289; called by muse, mutect2, varscan2
- ADGRG4 | c.7302A>G p.K2434= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV99794536; called by muse, mutect2, varscan2
- ALAS2 | c.564A>C p.S188= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV100238011; called by muse, mutect2, varscan2
- BOD1L1 | c.450G>A p.Q150= | Silent (SNP) | VAF 29/194 reads (15%) | catalogued as COSV99238527; called by muse, mutect2, varscan2
- BRINP1 | c.360C>T p.T120= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs867261587, COSV99774644; called by muse, mutect2, varscan2
- CNOT9 | c.867C>T p.T289= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs369273231; called by muse, mutect2, varscan2
- EHBP1L1 | c.2991C>T p.A997= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100499704; called by muse, mutect2
- ESRRB | c.1170C>A p.G390= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99834842; called by muse, mutect2, varscan2
- HHIP | c.204G>T p.L68= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV99666722; called by muse, mutect2, varscan2
- ISL2 | c.33G>A p.L11= | Silent (SNP) | VAF 50/582 reads (9%) | catalogued as COSV99320529; called by muse, mutect2
- LARS1 | c.1234T>C p.L412= (on ENST00000394434 / NM_020117.11; = p.L385= on NM_016460.3) | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as rs1231184427, COSV99198492; called by muse, mutect2
- MAST4 | c.4749G>A p.R1583= (on ENST00000403625 / NM_001164664.2; = p.R1394= on NM_015183.3) | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV99843098; called by muse, mutect2
- PCDHA12 | c.132C>T p.F44= | Silent (SNP) | VAF 20/199 reads (10%) | catalogued as rs782196068, COSV56474664; called by muse, mutect2, varscan2
- PPP1R10 | c.2346C>A p.R782= | Silent (SNP) | VAF 50/372 reads (13%) | catalogued as COSV100919757; called by muse, varscan2
- SERPINB3 | c.324C>T p.F108= | Silent (SNP) | VAF 28/296 reads (9%) | catalogued as rs376584936; called by muse, mutect2
- SOGA3 | c.684A>G p.G228= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100846803; called by muse, mutect2, varscan2
- TEK | c.1287G>A p.V429= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as COSV101193204; called by muse, mutect2, varscan2
- TJAP1 | c.1581C>T p.R527= (on ENST00000372445 / NM_001146016.1; = p.R517= on NM_080604.3) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV52504498; called by muse, mutect2, varscan2
- UGT2A1 | c.19C>T p.L7= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99683896; called by muse, mutect2, varscan2
- VPS8 | c.3141T>C p.T1047= (on ENST00000625842 / NM_001349294.1; = p.T1045= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99800948; called by muse, mutect2
- ZNF248 | c.366T>G p.T122= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV100627485; called by muse, mutect2, varscan2
- ZNF777 | c.2001C>T p.P667= | Silent (SNP) | VAF 90/349 reads (26%) | catalogued as rs779163338, COSV99924898; called by muse, mutect2, varscan2
- ZNF787 | c.1035G>A p.S345= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs757133525, COSV54417642; called by muse, mutect2, varscan2
- RIMS2 | c.1692+216G>T | Intron (SNP) | VAF 32/213 reads (15%) | catalogued as rs1240375055, COSV99170297; called by muse, mutect2, varscan2
